Gene-level copy-number profile of tumor specimen TCGA-LP-A4AX-01A from TCGA case TCGA-LP-A4AX, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 45.3 years (16,544 days).
Specimen TCGA-LP-A4AX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.47174a3a-d374-4f19-b977-be37e5a8d22b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LP-A4AX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/05a7207b-bd30-4578-9285-dbcbd72e7bcc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 8,376; copy number 2: 44,823; copy number 3: 4,693; copy number 4: 1,789; copy number 5: 77; copy number 8: 7; copy number 9: 2; copy number 67: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LP-A4AX-01A-12D-A242-01): tumor purity 0.45, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:228,850,526–230,580,006, 26 genes (within-gene range 0–1): PID1, RPL17P14, RN7SKP283, DNER, AC008273.1, RNU7-9P, AC007559.1, TRIP12, RNU6-613P, FBXO36, RNU6-964P, FBXO36-IT1, RNU6-1027P, SLC16A14, RNY4P19, AC009950.1, AC009950.2, SP110, SP140, SP140L, AC009949.1, SP100, RN7SL834P, HMGB1P3, AC010149.1, TPM3P8.
- chr13:81,018,176–81,691,072, 7 genes: LINC00377, DPPA3P3, LINC00564, AL353633.1, RNU6-77P, HIGD1AP2, PTMAP5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 103 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:200,305,881–200,748,040, 9 genes, copy number 8–9: SPATS2L, RNY4P34, AC012459.1, KCTD18, SGO2, AOX1, AOX3P, AOX3P-AOX2P, LINC01792.
- chr11:101,890,674–102,470,384, 17 genes, copy number 67 (within-gene range 1–67): ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1.
- chr18:47,390–927,993, 35 genes, copy number 5: TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904.
- chr19:7,868,719–8,577,577, 41 genes, copy number 5: PRR36, AC010336.3, LYPLA2P2, 5S_rRNA, LRRC8E, AC010336.1, MAP2K7, AC010336.4, TGFBR3L, AC010336.2, SNAPC2, CTXN1, AC010336.5, TIMM44, AC010336.7, ELAVL1, AC010336.6, AC008946.1, CCL25, FBN3, AC022146.1, CERS4, AC022146.2, CD320, AC010323.1, NDUFA7, RPS28, KANK3, AC010323.2, ANGPTL4, RAB11B-AS1, MIR4999, RAB11B, MARCHF2, AC136469.1, AC136469.2, HNRNPM, PRAM1, ZNF414, MYO1F, AC092316.1.
- chr19:8,581,160–8,582,715, 1 gene, copy number 5: AC130469.1.

Autosomal genes at a single copy (total copy number 1): 8,376. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
